Somatic mutation profile of tumor specimen MMRF_1266_1_BM_CD138pos (aliquot MMRF_1266_1_BM_CD138pos_T2_TSE61_K03760) from MMRF case MMRF_1266, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.2 years (27,094 days).
Specimen MMRF_1266_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c879737b-b87e-4b66-b005-02c689250796.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1266_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1266_1_PB_Whole_C1_TSE61_K03761; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89103644-7131-401b-aefb-f3d0f2a9e8dd

The open-access MAF lists 91 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 37, Missense Mutation 26, Silent 14, 5'UTR 4, 3'Flank 3, Frame Shift Del 2, Intron 2, RNA 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APLP1 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as COSV55707127; called by muse, mutect2, varscan2
- BTAF1 | c.3192T>A p.N1064K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56434182; called by muse, mutect2
- C1R | c.1897G>A p.A633T (on ENST00000536053 / NM_001354346.2; = p.A619T on NM_001733.7) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as rs760611749; called by muse, mutect2, varscan2
- CPA1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs369665148; called by muse, mutect2, varscan2
- CTNNA3 | c.2410G>A p.V804I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as rs370688983; called by muse, mutect2, varscan2
- HECTD3 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1557728786, COSV55798981; called by muse, mutect2
- LGALS12 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs201635291; called by muse, mutect2, varscan2
- MUC16 | c.17572G>A p.E5858K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV67447862, COSV67455077; called by muse, mutect2
- OR4X2 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV56585045; called by muse, mutect2
- RIPOR2 | c.1010A>C p.Q337P | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762773503; called by muse, mutect2, varscan2
- ZNF735 | c.1176G>A p.W392* | Nonsense Mutation (SNP) | VAF 110/230 reads (48%) | catalogued as rs575560193, COSV70034627; called by muse, mutect2, varscan2
- ALDH3B2 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.1481A>C p.K494T | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- COBLL1 | c.281A>C p.K94T (on ENST00000392717; = p.K56T on NM_014900.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- H3C11 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- KAT2A | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCTL | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NIFK | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NTRK3 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR9Q2 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- PAFAH1B3 | c.564T>A p.H188Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PRKD2 | c.1151T>A p.V384E | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRRC2C | c.4523A>G p.N1508S (on ENST00000367742; = p.N1506S on NM_015172.4) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC10A6 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SP140 | c.1369_1370del p.V457Hfs*18 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2
- THAP11 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMCO6 | c.100del p.R34Gfs*12 | Frame Shift Del (DEL) | VAF 31/61 reads (51%) | called by mutect2, pindel, varscan2
- UPF3A | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ZNF777 | c.2150C>G p.T717R | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS18 | c.3444C>A p.V1148= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV51422101; called by muse, mutect2, varscan2
- CEACAM5 | c.1464G>A p.R488= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs782270899; called by muse, mutect2, varscan2
- GFI1B | c.969C>T p.R323= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs755805333; called by muse, mutect2, varscan2
- GRTP1 | c.639G>A p.P213= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as rs370963142; called by muse, mutect2, varscan2
- LCA5 | c.912G>A p.K304= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PENK | c.450G>T p.L150= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.537G>C p.G179= | Silent (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- SIDT1 | c.681C>T p.L227= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs141350402; called by muse, mutect2, varscan2
- SLC12A9 | c.1419C>A p.I473= | Silent (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- SLC22A5 | c.930C>T p.S310= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1436750038; called by muse, mutect2, varscan2
- SLC5A1 | c.651C>A p.I217= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV56688178; called by muse, mutect2, varscan2
- SLC6A19 | c.816C>T p.G272= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as rs370546018; called by muse, mutect2, varscan2
- ZNF175 | c.1056G>A p.T352= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs770779812, COSV51795788; called by muse, mutect2, varscan2
- ZNF311 | c.189A>G p.S63= | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- AARS1 | c.-99G>C | 5'UTR (SNP) | VAF 15/32 reads (47%) | catalogued as rs964671312; called by muse, mutect2, varscan2
- AGMO | c.*921A>C | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- ANKRD2 | c.*106T>A | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2
- ANKRD28 | c.*2850C>G | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- ASZ1 | c.*150dup | 3'UTR (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- BMS1 | c.*393T>A | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- BNC2 | c.*824_*825del | 3'UTR (DEL) | VAF 32/85 reads (38%) | called by mutect2, pindel, varscan2
- CABLES1 | c.*2964T>C | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- CCDC107 | chr9:35657953 T>A | 5'Flank (SNP) | VAF 30/72 reads (42%) | catalogued as rs530883024; called by muse, mutect2, varscan2
- CCDC177 | c.*1399T>C | 3'UTR (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- CEBPD | c.*49C>T | 3'UTR (SNP) | VAF 7/10 reads (70%) | catalogued as rs374190201; called by muse, varscan2
- CFTR | c.*708_*752del | 3'UTR (DEL) | VAF 58/95 reads (61%) | called by mutect2, pindel
- CFTR | c.*1131A>T | 3'UTR (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- DNMBP | c.*893_*894del | 3'UTR (DEL) | VAF 51/123 reads (41%) | catalogued as rs1374545035; called by pindel, varscan2
- ETV1 | chr7:13894030 G>T | 3'Flank (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- GK | c.*751G>T | 3'UTR (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- GPHN | c.-685C>G | 5'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- HCN1 | c.*1665A>G | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- HSPA9 | c.-72C>T | 5'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as rs748668795; called by muse, varscan2
- LAPTM4B | c.*130T>C | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- LINC00242 | n.1923C>A | RNA (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- MAB21L1 | c.*845A>G | 3'UTR (SNP) | VAF 46/46 reads (100%) | called by muse, mutect2, varscan2
- MEN1 | c.*664C>G | 3'UTR (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- MOB1B | c.*2642G>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- MTM1 | c.*1398C>T | 3'UTR (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- NOL12 | c.*1417C>T | 3'UTR (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-37322A>G | Intron (SNP) | VAF 38/82 reads (46%) | catalogued as rs1195854223; called by muse, mutect2, varscan2
- NUDT11 | c.*110C>T | 3'UTR (SNP) | VAF 38/147 reads (26%) | catalogued as COSV101047086; called by muse, mutect2, varscan2
- OTX2 | c.*206A>C | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- PCLO | c.*166C>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- PHKA2 | c.*1122G>A | 3'UTR (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- PRPF40A | c.*284G>A | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- PTGDR | c.*229A>T | 3'UTR (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- PTPN18 | c.*1527C>T | 3'UTR (SNP) | VAF 66/116 reads (57%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.*3242A>C | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs891693645; called by mutect2, varscan2
- RAD18 | c.-85A>G | 5'UTR (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- RIMS1 | chr6:72401173 C>A | 3'Flank (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- RNF165 | c.*3968T>G | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- RPL23A | c.*14G>A | 3'UTR (SNP) | VAF 16/43 reads (37%) | catalogued as rs1441705036; called by muse, mutect2, varscan2
- SHROOM4 | c.*998-1296del | Intron (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- SLC30A9 | c.*301T>G | 3'UTR (SNP) | VAF 77/170 reads (45%) | called by muse, mutect2, varscan2
- SLC39A14 | chr8:22421072 G>T | 3'Flank (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- SOX3 | c.*201C>G | 3'UTR (SNP) | VAF 46/99 reads (46%) | catalogued as rs1220667972; called by muse, mutect2, varscan2
- TENT5A | c.*1419del | 3'UTR (DEL) | VAF 12/28 reads (43%) | catalogued as rs961290506; called by mutect2, varscan2
- TMPRSS3 | c.*148C>T | 3'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs1189113483; called by muse, mutect2
- XKR4 | c.*1522G>T | 3'UTR (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- ZBTB34 | c.*2043T>G | 3'UTR (SNP) | VAF 29/52 reads (56%) | catalogued as rs1250594610; called by muse, mutect2, varscan2
- ZC3H12B | c.*3430C>G | 3'UTR (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
